Somatic mutation profile of tumor specimen TCGA-FG-A4MX-01A (aliquot TCGA-FG-A4MX-01A-11D-A26M-08) from TCGA case TCGA-FG-A4MX, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Frontal lobe; Tumor grade: G2; Age at diagnosis: 47.6 years (17,381 days).
Specimen TCGA-FG-A4MX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 105a24c7-bac6-4eb7-b9e5-bc785f57a935.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A4MX-10A (Blood Derived Normal), aliquot TCGA-FG-A4MX-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/485f3184-db55-4f28-8dea-6e484c15a229

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 16, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 83/95 reads (87%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs786202752, CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ATRX | c.5635T>G p.L1879V | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64871433; called by muse, mutect2, varscan2
- CCNB2 | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV55594822; called by muse, mutect2, varscan2
- CFTR | c.1891T>C p.S631P | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV50041016; called by muse, mutect2, varscan2
- DROSHA | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.272); catalogued as COSV60772521; called by muse, mutect2, varscan2
- EIF3L | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV67739343, COSV67739607; called by muse, mutect2, varscan2
- EPG5 | c.901A>G p.R301G | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56344565; called by muse, mutect2, varscan2
- EXT1 | c.1217A>G p.Q406R | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV65475052; called by muse, mutect2, varscan2
- FREM1 | c.3357C>A p.D1119E | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761057149, COSV66517822; called by muse, mutect2
- FSCN3 | c.1420T>C p.Y474H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56169020; called by muse, mutect2, varscan2
- LGI1 | c.1402A>G p.I468V | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65057434; called by muse, mutect2, varscan2
- MEIS3 | c.970A>G p.M324V (on ENST00000558555 / NM_001346148.1; = p.M370V on NM_020160.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs748224833, COSV58982848; called by muse, varscan2
- PDCD11 | c.3128T>C p.V1043A | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63933009; called by muse, mutect2
- RAD51AP2 | c.383G>T p.R128M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV67587322; called by muse, mutect2, varscan2
- SLC35G6 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV59489204; called by muse, mutect2, varscan2
- ZMYM2 | c.3583C>T p.R1195* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV67032086; called by muse, mutect2, varscan2
- REV3L | c.5508_5511del p.D1836Efs*12 | Frame Shift Del (DEL) | VAF 35/122 reads (29%) | called by mutect2, pindel, varscan2
- MAP1S | c.3150C>T p.D1050= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs776155424, COSV60721541; called by muse, mutect2, varscan2
- TOGARAM2 | c.186G>A p.P62= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs575618435, COSV65419834; called by muse, mutect2, varscan2
